Somatic mutation profile of tumor specimen TCGA-LN-A4A5-01A (aliquot TCGA-LN-A4A5-01A-21D-A27G-09) from TCGA case TCGA-LN-A4A5, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G2; Age at diagnosis: 49.7 years (18,160 days).
Specimen TCGA-LN-A4A5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7d76be06-1db3-496a-83f2-1fb98f7a5d6c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-LN-A4A5-10A (Blood Derived Normal), aliquot TCGA-LN-A4A5-10A-01D-A27G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04d6708f-9eb4-40df-b2ea-e1a8d51425d3

The open-access MAF lists 66 somatic variants for this specimen: 52 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 47, Silent 14, Frame Shift Ins 3, Splice Region 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 240/447 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGO4 | c.313A>G p.M105V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs779332147; called by muse, mutect2, varscan2
- C9orf43 | c.711G>T p.L237F | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781076077; called by muse, mutect2
- CIR1 | c.929A>G p.K310R | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs777532880; called by muse, mutect2, varscan2
- COL15A1 | c.2796C>T p.G932= | Splice Region (SNP) | VAF 21/58 reads (36%) | catalogued as COSV66648984; called by muse, mutect2, varscan2
- CTNNA2 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV63603973; called by muse, mutect2, varscan2
- GSDMA | c.164G>T p.R55L | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.154); catalogued as rs767159876; called by muse, mutect2, varscan2
- IGBP1P2 | c.254C>T p.A85V | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.534); catalogued as rs1254725950; called by muse, mutect2, varscan2
- ITGA7 | c.991C>A p.R331S (on ENST00000555728; = p.R287S on NM_002206.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs563941470, COSV57693084; called by muse, mutect2, varscan2
- MBTPS2 | c.124G>A p.G42R | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs375900835; called by muse, mutect2, varscan2
- MYH4 | c.5117C>A p.A1706E | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs769268117; called by muse, mutect2, varscan2
- PCLO | c.9646T>G p.L3216V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as rs750254988, COSV100439759; called by mutect2, varscan2
- PIP5K1C | c.1451G>A p.R484Q | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs778345965, COSV100096262; called by muse, mutect2, varscan2
- PRKACA | c.673C>A p.L225M | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV58069446; called by muse, mutect2, varscan2
- PTPRU | c.3851C>A p.S1284Y | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as COSV60526404; called by muse, mutect2, varscan2
- RNF19A | c.104A>G p.H35R | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); catalogued as rs761833362; called by muse, mutect2, varscan2
- SH2D1B | c.376G>T p.D126Y | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV63392408; called by muse, mutect2, varscan2
- SH2D2A | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV63885151; called by muse, mutect2, varscan2
- SH2D2A | c.673G>T p.A225S | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV63885263, COSV63885558; called by muse, mutect2, varscan2
- SPTBN2 | c.5446C>T p.R1816W | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.954); catalogued as rs757668466, COSV59452266; called by muse, mutect2, varscan2
- WDR70 | c.1625C>T p.P542L | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.084); catalogued as rs756805874; called by muse, mutect2, varscan2
- ZMYND19 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs1235562329, COSV100057285; called by muse, mutect2, varscan2
- AKT3 | c.1261C>A p.P421T | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2
- ASPM | c.7425G>T p.K2475N | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ASTL | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ATAD3A | c.986A>T p.K329M | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- C12orf66 | c.438G>T p.M146I | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CAPN6 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- CDH22 | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CERS5 | c.569A>G p.Y190C | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- COL8A1 | c.1317G>T p.K439N | Missense Mutation (SNP) | VAF 11/65 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.203); called by muse, mutect2, varscan2
- DPP7 | c.626T>A p.F209Y | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.622); called by muse, mutect2, varscan2
- ESR2 | c.434A>G p.D145G | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); called by muse, mutect2, varscan2
- FEZF2 | c.1185C>G p.N395K | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- FLAD1 | c.659T>G p.L220R | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- GPR83 | c.612dup p.A205Cfs*13 | Frame Shift Ins (INS) | VAF 17/84 reads (20%) | called by mutect2, pindel, varscan2
- H2AC15 | c.335dup p.Q113Pfs*7 | Frame Shift Ins (INS) | VAF 21/180 reads (12%) | called by mutect2, pindel, varscan2
- HUWE1 | c.10823T>G p.L3608R | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- LEMD3 | c.770A>T p.N257I | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.094); called by muse, mutect2
- LRPPRC | c.1532G>T p.G511V | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- MAB21L2 | c.507A>T p.Q169H | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- MCC | c.1856dup p.M619Ifs*47 | Frame Shift Ins (INS) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- MTHFD1L | c.1213A>G p.R405G | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- MTOR | c.2464A>G p.I822V | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MYH15 | c.4641A>T p.E1547D | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2
- RBMXL1 | c.818C>T p.S273L | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.366); called by muse, mutect2, varscan2
- RCN1 | c.224T>A p.L75H | Missense Mutation (SNP) | VAF 10/266 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- SIRPG | c.179C>G p.P60R | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SYNE2 | c.9575G>T p.C3192F | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.231); called by muse, mutect2, varscan2
- TTI1 | c.1973A>T p.E658V | Missense Mutation (SNP) | VAF 12/63 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- WNT3A | c.227A>T p.E76V | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZGRF1 | c.3970T>C p.S1324P | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- APOA1 | c.474G>A p.L158= | Silent (SNP) | VAF 3/34 reads (9%) | called by muse, mutect2
- ASXL3 | c.3276G>A p.E1092= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV52463832; called by muse, mutect2, varscan2
- ATP13A1 | c.3027A>T p.G1009= | Silent (SNP) | VAF 5/29 reads (17%) | called by muse, mutect2, varscan2
- FUT5 | c.699C>T p.D233= | Silent (SNP) | VAF 13/78 reads (17%) | catalogued as rs763176772; called by muse, mutect2, varscan2
- MBP | c.849G>A p.T283= (on ENST00000355994 / NM_001025101.2; = p.T165= on NM_002385.3) | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs747036508; called by muse, mutect2, varscan2
- MCF2L2 | c.2295G>C p.L765= | Silent (SNP) | VAF 6/23 reads (26%) | called by muse, mutect2
- MSL2 | c.318A>G p.L106= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs544521594; called by muse, mutect2, varscan2
- OGT | c.2208G>C p.L736= | Silent (SNP) | VAF 4/28 reads (14%) | called by muse, mutect2, varscan2
- PIEZO2 | c.7368C>T p.A2456= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- PTPRU | c.3852C>A p.S1284= | Silent (SNP) | VAF 10/64 reads (16%) | called by muse, mutect2, varscan2
- QTRT1 | c.159C>T p.T53= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- TLN2 | c.4167C>G p.L1389= | Silent (SNP) | VAF 13/85 reads (15%) | called by muse, mutect2, varscan2
- TTN | c.56523T>C p.C18841= (on ENST00000591111; = p.C11417= on NM_003319.4) | Silent (SNP) | VAF 21/103 reads (20%) | called by muse, mutect2, varscan2
- ZBTB22 | c.279C>T p.S93= | Silent (SNP) | VAF 12/61 reads (20%) | called by muse, mutect2, varscan2
